Surgical pathology report (de-identified scan), TCGA case TCGA-XR-A8TE, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-XR-A8TE-01A (Primary Tumor).

[page 1 of 2]
IIQ-0-3
Carcinoma, hepatocellular
NOS 8/20/3
Site: Liver C22.0
9/21/29/14

Nature of material: Lymph node
Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACOSCOPY

Received six identified vials.

Vial 1. Lymph nodes of the hepatic hilum:

- Irregular and fibro-adipose structure measuring 4.3 x 3.9 x 1.9 cm. Fourteen hardened and blackened lymph nodes were dissected, measuring between 0.2 and 4.2 x 1.8 x 1, 4 cm.

Vial 2. Lymph nodes of the celiac trunk:

- Irregular and fibro-adipose structure measuring 3.0 x 2.7 x 1.0 cm. Ten hardened and blackened structures were dissected measuring between 0.4 x 0.3 x 0.2 cm and 1.7 x 1.1 x 0.6 cm.

Vial 3. Surgical margin of segment I:

- Irregular, firm and greyish fragment, which measures 3.3 x 1.2 x 1.2 cm. There is a firm and whitish mass, poorly demarcated, close to the capsule, measuring 1.3 x 0.4 cm in size.

Vial 4. Diaphragmatic lesion:

- Two irregular, elastic and brownish fragments, measuring together 1.2 x 1.2 x 0.5 cm.

Vial 5. Left gastric artery lymph nodes:

- Two irregular and fibro-adipose structures together measuring 2.5 x 2.0 x 1.9 cm. Eleven hardened and blackish-brown lymph nodes were dissected, measuring between 0.2 and 1.4 x 0.7 x 0.5 cm in diameter.

Vial 6. Partial hepatectomy (segments IV, V, VI, VII and VIII):

- Portion of liver tissue, previously sectioned along the longest axis, weighing 2770.0 g and measuring 18.0 x 18.0 x 10.1 cm. The capsular surface is smooth, brownish, slightly congested, with indurated nodules. The parenchyma is soft and brownish and shows a well-defined, lobulated and firm mass, with whitish to greenish and hemorrhagic areas, measuring 18.0 cm in the longest axis. It is accompanied closed gallbladder, measuring 6.5 cm long, 2.7 cm in fund diameter and 0.7 cm in duct diameter. The surface is smooth and congested and mucosa is greenish and covered with thick bile.

MICROSCOPY

Expendable description.

DIAGNOSTIC

Product of partial hepatectomy and lymphadenectomy:

- Main part (vial 6): Well-differentiated hepatocellular carcinoma, with trabecular and pseudo acinar pattern with 18.0 cm in the longest axis, and the presence of multiple smaller tumor nodules adjacent to the main lesion.
- Absence of well defined angiolymphatic invasion in the examined sections.
- Free margins.
- Adjacent non-neoplastic liver parenchyma without significant fibrosis, with slight modifications secondary to tumor mass effect, such as ductal proliferation, foci of chronic inflammation and mild portal chronic cholestasis.
- Gallbladder without histopathological changes.

[page 2 of 2]
- Hepatic parenchyma identified as surgical margin (vial 3) free of neoplastic invasion.
- Diaphragmatic lesion (vial 4): dense fibrous connective tissue with mild lymphocytic inflammatory infiltrate and areas of congestion without signs of malignancy.
- Lymph nodes of the hepatic hilum (vial 1): absence of neoplastic invasion in the fourteen examined lymph nodes (0/14).
- Lymph nodes of the celiac trunk (vial 2): absence of invasion in the seven examined lymph nodes (0/7).
- Lymph nodes of the left gastric artery (vial 5): absence of invasion in the eleven examined lymph nodes (0/11).

NOTES:

It was performed immunohistochemical study of the tumor, which shows positivity for cytokeratin of low weight (cam5.2), and canalicular positivity pattern for polyclonal CEA (carcino-embryonic antigen), which is specific for hepatocellular carcinoma type. It was found negativity for HSA (Hepatocyte-specific antigen), which may occur in rare cases. And there was negativity for CK7, disfavoring the hypothesis of fibrolamellar variant (which is generally positive for this marker).

Pathological staging: PT3A pN0.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Write in	Yes	No
Tumor-Tumor Site Discrepancy		✓
IPSA Discrepancy		✓

Source: NCI Genomic Data Commons file fdbbb646-66a2-4abc-b9a5-cbae2fd920d4 (TCGA-XR-A8TE.D020A2B1-03B7-490C-AFA4-BBE3EB661CA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).